Somatic mutation profile of tumor specimen TCGA-A4-7734-01A (aliquot TCGA-A4-7734-01A-11D-2136-08) from TCGA case TCGA-A4-7734, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.7 years (19,612 days).
Specimen TCGA-A4-7734-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) befca2ba-e82a-4c09-9b07-24dce18a36c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7734-10A (Blood Derived Normal), aliquot TCGA-A4-7734-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44aa7f95-0c72-4474-b565-bd55952b05cf

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 3, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD4 | c.1375C>A p.L459M | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53992869; called by muse, mutect2, varscan2
- ADGRG3 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59651360; called by muse, mutect2, varscan2
- APOB | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 51/131 reads (39%) | catalogued as COSV51938966; called by muse, mutect2, varscan2
- BAHCC1 | c.5572G>T p.E1858* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57027922; called by muse, mutect2, varscan2
- CAMK2A | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV100804443, COSV62246661; called by muse, mutect2, varscan2
- CAPN1 | c.1538T>G p.F513C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54199170; called by muse, mutect2, varscan2
- CIC | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs776579231, COSV50589123, COSV50671387; called by muse, mutect2, varscan2
- CLTC | c.275A>T p.N92I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52248545; called by muse, mutect2, varscan2
- CPM | c.139A>T p.S47C | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV58033805; called by muse, mutect2, varscan2
- CUBN | c.2079A>C p.Q693H | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV64718021; called by muse, mutect2, varscan2
- DUSP6 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54378853; called by muse, mutect2, varscan2
- FCHO2 | c.2189A>C p.E730A | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV59273811; called by muse, mutect2, varscan2
- FOCAD | c.5031T>A p.F1677L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV58101065; called by muse, mutect2, varscan2
- H2AJ | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV63762152; called by muse, mutect2, varscan2
- ITGA6 | c.2569C>A p.Q857K (on ENST00000442250; = p.Q818K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV51228701; called by muse, mutect2, varscan2
- KIF13A | c.2929A>C p.T977P | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52454145; called by muse, mutect2, varscan2
- KIFC3 | c.318A>G p.V106= | Splice Region (SNP) | VAF 30/74 reads (41%) | catalogued as COSV65550910; called by muse, mutect2, varscan2
- LUC7L3 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.171); catalogued as COSV53587478; called by muse, mutect2, varscan2
- MACF1 | c.7979T>G p.I2660S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV57125791; called by muse, mutect2, varscan2
- MET | c.3708T>A p.S1236R | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59262509; called by muse, mutect2, varscan2
- MYO1C | c.3065+2T>G p.X1022_splice (on ENST00000648651 / NM_001080779.2; = p.X987_splice on NM_033375.5) | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as COSV62999432, COSV62999554; called by muse, mutect2, varscan2
- NEK10 | c.2078T>A p.I693N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58284657; called by muse, mutect2, varscan2
- NSUN2 | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52955002; called by muse, mutect2
- PDCL | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 54/151 reads (36%) | catalogued as COSV52342722; called by muse, mutect2, varscan2
- PPIB | c.136-2A>G p.X46_splice | Splice Site (SNP) | VAF 74/175 reads (42%) | catalogued as COSV55520414; called by muse, mutect2, varscan2
- PTPRJ | c.3543T>A p.D1181E | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV69252688; called by muse, mutect2, varscan2
- RNF26 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs200033048; called by muse, mutect2, varscan2
- SLC2A8 | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64894653; called by muse, mutect2, varscan2
- SLC37A1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61402790; called by muse, mutect2, varscan2
- SMC5 | c.1274G>C p.R425P | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); catalogued as COSV63193476, COSV63195253; called by muse, mutect2, varscan2
- SPAM1 | c.1502T>A p.L501H | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as COSV99772977; called by muse, mutect2, varscan2
- TAS1R2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201197024, COSV64744384; called by muse, mutect2, varscan2
- TBCB | c.66C>G p.F22L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52900369; called by muse, mutect2, varscan2
- TUBB1 | c.68T>C p.M23T | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs374942824; called by muse, mutect2, varscan2
- TYW1 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV62753103; called by muse, mutect2, varscan2
- VPS13A | c.8395A>C p.I2799L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV62431444; called by muse, mutect2, varscan2
- VPS28 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV52872359; called by muse, mutect2, varscan2
- YY1AP1 | c.989T>A p.M330K (on ENST00000295566 / NM_139118.2; = p.M273K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55121913; called by muse, mutect2, varscan2
- NEDD4 | c.96_99del p.M33Afs*16 | Frame Shift Del (DEL) | VAF 67/210 reads (32%) | called by mutect2, pindel, varscan2
- SON | c.5664del p.E1889Rfs*117 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- TMCC2 | c.1799_1818+10del p.X600_splice | Splice Site (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel
- ZNF385B | c.969del p.K323Nfs*25 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- ARID5B | c.3085C>A p.R1029= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV54413908, COSV54422079; called by muse, mutect2, varscan2
- DST | c.11232A>G p.A3744= (on ENST00000361203 / NM_001374722.1; = p.A1332= on NM_015548.5) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs762128348, COSV55019716; called by muse, mutect2, varscan2
- FAT4 | c.13959C>A p.I4653= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV58689918; called by muse, mutect2, varscan2
- HERC5 | c.2055C>G p.V685= | Silent (SNP) | VAF 93/207 reads (45%) | catalogued as COSV52040708; called by muse, mutect2, varscan2
- KCND3 | c.633G>A p.P211= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs35131566, COSV100137240; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL40 | c.21G>A p.Q7= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV55134947; called by muse, varscan2
- NECTIN4 | c.414G>A p.Q138= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2
- NEK10 | c.2079C>T p.I693= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV58284629; called by muse, mutect2, varscan2
- PKHD1L1 | c.1929G>C p.G643= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV65745039; called by muse, mutect2, varscan2
- ZNF644 | c.795C>T p.F265= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV61348213; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504401 T>C | 5'Flank (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- FRMPD2B | n.1252G>A | RNA (SNP) | VAF 30/86 reads (35%) | called by mutect2, varscan2
